EXCEPTIONAL_RESPONDERS case ER-ABXO — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/16c75914-cac8-4e47-b156-4ee9571cab58

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Year of birth: 1945; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Colon, NOS; Site of resection or biopsy: Colon, NOS; Classification of tumor: metastasis; Age at diagnosis: 66.0 years (24,107 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic stage: Stage IVB; Prior malignancy: no; Days to last follow up: 515 days (1.4 years); Days to best overall response: 515 days (1.4 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Bevacizumab + Fluorouracil + Leucovorin Calcium + Oxaliplatin; Days to treatment start: 28 days; Days to treatment end: 1,549 days (4.2 years).

Follow-up (1 entry)
- Days to follow up: 515 days (1.4 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 10 days; Days progression-free: 515 days (1.4 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ABXO-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: FFPE.
  Slide ER-ABXO-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 10; Percent tumor nuclei: 5; Percent normal cells: 15; Percent necrosis: 75; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
